Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5187, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5187-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Right renal mass.

TCGA-BP-5187

Specimens Submitted:

1: Kidney, right upper pole, partial nephrectomy

DIAGNOSIS:

1. Kidney, right upper pole, partial nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 3.5 cm. ✓

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Focal chronic inflammation and vascular sclerosis

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh labeled "Right upper pole partial nephrectomy". It consists of a 50 g, 4.5 x 4.5 x 3.5 cm portion of renal parenchyma with attached fat measuring 7.1 x 3.8 x 2.2 cm. The resected margin of the specimen is inked black. The specimen is sectioned to reveal a 3.5 x 3.2 x 2.5 cm well circumscribed hemorrhagic mass which is located 0.5 cm from the closest resected margin. The mass abuts the renal capsule but does not grossly involve it. The remainder of the renal parenchyma is brown-tan and grossly unremarkable. Representative sections are submitted. A sample of the tumor is given to TPS.

Summary of sections:

TM-tumor with margin

TC-tumor with renal capsule

RS-representative section of uninvolved kidney

TN-tumor with normal kidney

Summary of Sections:

Part 1: Kidney, right upper pole, partial nephrectomy

Block	Sect. Site	PCs
1	fsc	1
1	rs	1
1	tc	1
2	tm	2

Source: NCI Genomic Data Commons file e256bad3-3592-4de6-9176-46e3bd60deab (TCGA-BP-5187.C30D90F6-815C-477D-A270-CFBD9F5804BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).